Somatic mutation profile of tumor specimen TCGA-12-3651-01A (aliquot TCGA-12-3651-01A-01W-0922-08) from TCGA case TCGA-12-3651, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.4 years (28,277 days).
Specimen TCGA-12-3651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a8d927d-1d71-43c3-a73e-62f3e50f08d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3651-10A (Blood Derived Normal), aliquot TCGA-12-3651-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae44838b-6db1-421d-b7b4-aee7a7933985

The open-access MAF lists 101 somatic variants for this specimen: 85 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 15, Splice Region 5, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.2362G>C p.E788Q | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV52008290, COSV99326963, COSV99327897; called by muse, mutect2
- ACSM2B | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 28/850 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV100312632; called by muse, mutect2
- ADAM7 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs767236507, COSV51542203, COSV99443834; called by muse, mutect2, varscan2
- ANKS1B | c.2506T>C p.F836L (on ENST00000547776 / NM_152788.4; = p.F62L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/510 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100227880; called by muse, mutect2, varscan2
- ARHGEF15 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs926440781, COSV100730039; called by muse, mutect2, varscan2
- ARMC3 | c.1671C>A p.S557R | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99958020; called by muse, mutect2
- ATP1A3 | c.1676G>C p.C559S (on ENST00000545399 / NM_001256214.2; = p.C546S on NM_152296.5) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV100132233; called by muse, mutect2
- ATP4A | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV99382549; called by muse, mutect2, varscan2
- ATP8B2 | c.3472C>T p.R1158W (on ENST00000672630; = p.R1125W on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764653687, COSV100874488; called by muse, mutect2, varscan2
- C2CD6 | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99632875; called by muse, mutect2, varscan2
- C3orf33 | c.170G>A p.R57Q (on ENST00000340171 / NM_001308229.2; = p.R14Q on NM_173657.2) | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs1447640415, COSV100420070; called by muse, mutect2, varscan2
- C9orf72 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as rs770323658, COSV101186513; called by muse, mutect2, varscan2
- CABIN1 | c.1703C>A p.P568H | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99573152; called by muse, mutect2, varscan2
- CAPRIN2 | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195491; called by muse, mutect2, varscan2
- CAPRIN2 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99195492; called by muse, mutect2, varscan2
- CDK20 | c.564G>C p.W188C (on ENST00000325303 / NM_001039803.3; = p.R167S on NM_012119.4) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519438, COSV100308072; called by muse, mutect2
- CHCHD7 | c.54G>A p.S18= (on ENST00000355315 / NM_001011671.3; = p.S30= on NM_024300.4) | Splice Region (SNP) | VAF 13/28 reads (46%) | catalogued as rs768823048, COSV57614471; called by muse, mutect2, varscan2
- CHP2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573488303, COSV55650157; called by muse, mutect2, varscan2
- DDX59 | c.860T>G p.I287R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100494528; called by muse, mutect2, varscan2
- DMKN | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100303559; called by muse, mutect2, varscan2
- DNAH11 | c.10471C>T p.R3491C | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162504533, COSV60937534; called by muse, mutect2, varscan2
- DOCK2 | c.4210C>T p.Q1404* | Nonsense Mutation (SNP) | VAF 8/155 reads (5%) | catalogued as COSV99912155; called by muse, mutect2
- DPYD | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV100928996; called by muse, mutect2, varscan2
- DSG4 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs530136665, COSV100355866; called by muse, mutect2, varscan2
- DYNC2H1 | c.5992A>G p.K1998E | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV100518484; called by muse, mutect2
- ELAPOR1 | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV100884678; called by muse, mutect2, varscan2
- ENPP2 | c.1265A>G p.K422R (on ENST00000075322 / NM_001040092.3; = p.K474R on NM_006209.5) | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs750980378, COSV99308227; called by muse, mutect2, varscan2
- FAT4 | c.5310T>C p.G1770= | Splice Region (SNP) | VAF 44/148 reads (30%) | catalogued as COSV100628523; called by muse, mutect2, varscan2
- FN1 | c.5273C>T p.P1758L | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100117073; called by muse, mutect2, varscan2
- FOXP2 | c.1770-2A>G p.X590_splice | Splice Site (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100646662; called by mutect2, varscan2
- GAPVD1 | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as rs745509501, COSV99783144; called by muse, mutect2, varscan2
- GDF9 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 53/270 reads (20%) | catalogued as COSV99737337; called by muse, mutect2, varscan2
- GPRC6A | c.1816A>T p.I606L | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100114353; called by muse, mutect2, varscan2
- HAUS8 | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV99505275; called by muse, mutect2, varscan2
- HMCN1 | c.11762C>T p.S3921L | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs12135336, COSV54933151; called by muse, mutect2, varscan2
- HTR3A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as rs150760041; called by muse, mutect2, varscan2
- IGKV5-2 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs183891175; called by muse, mutect2, varscan2
- KCNH5 | c.11dup p.K5Qfs*21 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | catalogued as rs769410349; called by mutect2, pindel, varscan2
- KCNK9 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.312); catalogued as COSV100270934; called by muse, mutect2, varscan2
- KIF2B | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1244887258, COSV52127228, COSV52133888; called by muse, mutect2, varscan2
- KLHDC3 | c.732C>T p.A244= | Splice Region (SNP) | VAF 169/245 reads (69%) | catalogued as rs1235240766, COSV99763727; called by muse, mutect2, varscan2
- KLRC1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100760807; called by muse, mutect2, varscan2
- LCE2C | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 118/445 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV100909434; called by muse, varscan2
- LCN1 | c.220C>T p.L74= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs771477955; called by muse, varscan2
- MDN1 | c.16720G>A p.A5574T | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs774441685, COSV65521738; called by muse, mutect2, varscan2
- MIA3 | c.5573C>T p.T1858I | Missense Mutation (SNP) | VAF 98/827 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100388241; called by muse, mutect2, varscan2
- MUC5AC | c.14396G>A p.R4799H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as rs760524829, COSV100611480; called by muse, varscan2
- MUC5B | c.5687C>T p.T1896M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); catalogued as rs147103997; called by muse, mutect2, varscan2
- NCOA1 | c.3977C>T p.T1326M | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs759588390, COSV56055876; called by muse, mutect2
- NINL | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99625286; called by muse, mutect2, varscan2
- NQO2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs373177858; called by muse, mutect2, varscan2
- OR2H1 | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 206/498 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV101009848; called by muse, varscan2
- PCDHA3 | c.1967A>C p.E656A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV100793408; called by muse, mutect2, varscan2
- PCDHA7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); catalogued as rs781952009, COSV65342627; called by muse, mutect2, varscan2
- PDGFC | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99925272; called by muse, mutect2, varscan2
- PIWIL3 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100177606; called by muse, mutect2, varscan2
- PKD1L1 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1220213349, COSV99219592; called by muse, mutect2
- PKHD1 | c.6120C>T p.H2040= | Splice Region (SNP) | VAF 289/799 reads (36%) | catalogued as rs747414274, COSV100582986; called by muse, mutect2, varscan2
- PKHD1 | c.3145C>A p.L1049M | Missense Mutation (SNP) | VAF 89/319 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100582988; called by muse, mutect2, varscan2
- PKN1 | c.2194C>A p.H732N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99466425; called by muse, mutect2, varscan2
- PLCG2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 210/767 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63877876; called by muse, mutect2, varscan2
- QSER1 | c.2927C>T p.P976L (on ENST00000399302; = p.P1105L on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101234837; called by muse, mutect2, varscan2
- RASGRP3 | c.1163A>G p.Q388R (on ENST00000402538 / NM_001349975.2; = p.X388_splice on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.258); catalogued as COSV101274749; called by muse, mutect2, varscan2
- RASIP1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99710732; called by muse, varscan2
- RCN2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV58031019; called by muse, mutect2, varscan2
- REEP1 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 146/1056 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1553465460, CD118424, COSV99382805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 74/1165 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100633768; called by muse, mutect2
- SERPINB8 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV99729156; called by muse, mutect2, varscan2
- SLC16A5 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 276/711 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100317086; called by muse, mutect2, varscan2
- SLC36A3 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as rs137910049; called by muse, mutect2, varscan2
- SPAG9 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100005141; called by muse, mutect2
- SPNS2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs768890918, COSV61229309; called by muse, mutect2, varscan2
- STMN4 | c.448G>A p.E150K (on ENST00000265770 / NM_001283054.2; = p.E177K on NM_030795.4) | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99740838; called by muse, mutect2, varscan2
- TMC3 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 123/590 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as COSV100845906; called by muse, mutect2, varscan2
- TNFRSF21 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99729553; called by muse, mutect2
- TNRC18 | c.6314G>A p.G2105E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100078786; called by muse, mutect2, varscan2
- TRIML2 | c.1179C>A p.Y393* | Nonsense Mutation (SNP) | VAF 59/248 reads (24%) | catalogued as COSV100456056; called by muse, mutect2, varscan2
- TRPM6 | c.1051A>T p.I351F | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1470555327, COSV100666282; called by muse, mutect2, varscan2
- TULP4 | c.3715A>T p.T1239S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV100893469; called by muse, mutect2, varscan2
- WNT9A | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs980670119, COSV55296730; called by muse, mutect2, varscan2
- ZNF226 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56196625; called by muse, mutect2
- ZNF654 | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1222883855, COSV100525712; called by muse, mutect2, varscan2
- ZSCAN30 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV99734895; called by muse, mutect2, varscan2
- GUCY2C | c.1686dup p.Y563Ifs*3 | Frame Shift Ins (INS) | VAF 59/216 reads (27%) | called by mutect2, pindel, varscan2
- PIK3CA | c.310_330del p.P104_E110del | In Frame Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel
- ABAT | c.990C>T p.T330= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs369874487; called by muse, mutect2, varscan2
- ALPK2 | c.2022A>T p.S674= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100864342; called by muse, mutect2, varscan2
- CREB3L3 | c.957G>A p.Q319= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99314139; called by muse, mutect2, varscan2
- DHX32 | c.2073G>A p.Q691= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV99501632; called by muse, mutect2, varscan2
- GALNT17 | c.1704C>T p.C568= | Silent (SNP) | VAF 70/252 reads (28%) | catalogued as COSV61196196; called by muse, mutect2, varscan2
- MAP7D2 | c.1041G>A p.L347= | Silent (SNP) | VAF 133/189 reads (70%) | catalogued as COSV101107351; called by muse, mutect2, varscan2
- MYOM1 | c.3315C>T p.L1105= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV99866556; called by muse, mutect2, varscan2
- NBAS | c.2862A>G p.L954= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV99869398; called by muse, mutect2, varscan2
- OR3A1 | c.474C>T p.N158= | Silent (SNP) | VAF 152/915 reads (17%) | catalogued as rs752671269, COSV60163498; called by muse, mutect2, varscan2
- PAQR3 | c.138C>T p.I46= | Silent (SNP) | VAF 202/324 reads (62%) | catalogued as COSV99785069; called by muse, mutect2, varscan2
- PRR23B | c.483C>T p.P161= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV61494705; called by muse, mutect2, varscan2
- PTDSS2 | c.762C>T p.N254= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs769812891, COSV100339153; called by muse, mutect2, varscan2
- RABGAP1 | c.312C>T p.S104= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100438562; called by muse, mutect2, varscan2
- SYK | c.1290G>A p.P430= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs539643362, COSV101002449; called by muse, mutect2, varscan2
- TREML2 | c.363G>A p.L121= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV72439256; called by muse, mutect2, varscan2
- GCNT2 | c.925+26655_925+26656del | Intron (DEL) | VAF 96/366 reads (26%) | called by pindel, varscan2
